Somatic mutation profile of tumor specimen 0DQFJ5 from CCDI case PBCEVY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Granulosa cell tumor, juvenile; Tissue or organ of origin: Ovary; Age at diagnosis: 0.7 years (266 days).
Specimen 0DQFJ5: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b3b4705-525a-45d3-b33c-32edf26c8cff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQFIX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1c30f29-ed2b-47de-9a88-4da144a1ea6a

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>A p.R201S | Missense Mutation (SNP) | VAF 232/586 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic; called by mutect2, varscan2
- ACSBG1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs762790030; called by muse, mutect2, varscan2
- TJP2 | c.2880+81G>A | Intron (SNP) | VAF 144/362 reads (40%) | called by muse, mutect2, varscan2
